TCGA case TCGA-EA-A43B — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3265f9c1-7242-4c7d-b4ad-b6519ee94f84

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 43.5 years (15,871 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 24.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Fluorouracil; Days to treatment start: 70 days; Days to treatment end: 70 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 70 days; Days to treatment end: 131 days; Treatment dose: 82 Gy; Treatment outcome: Complete Response; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 70 days; Days to treatment end: 131 days; Treatment dose: 35 Gy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.

Follow-up (9 entries)
- Day 36 (preoperative): Days to imaging: 36 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 36 (preoperative): Days to imaging: 36 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 36 (preoperative): Days to imaging: 36 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 36 (preoperative): Days to imaging: 36 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Parametrium Involvement.
- Day 36 (preoperative): Days to imaging: 36 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 36 (preoperative): Days to imaging: 36 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 53 (preoperative): ECOG performance status: 0.
- Days to follow up: 55 days; Disease response: Tumor Free.
- Days to follow up: 791 days (2.2 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 164 cm; BMI: 26.8.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EA-A43B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 540 mg.
  Slide TCGA-EA-A43B-01A-08-TSH: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 30; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample TCGA-EA-A43B-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EA-A43B-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 2; Total pregnancy count: 2; Tobacco smoking history indicator: 1; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; New tumor event diagnosis indicator: No.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Present; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Radiation therapy info: Brachytherapy type: LDR; Brachytherapy total dose point a: 3500; Radiation therapy xrt type: External beam radiation; Radiation treatment total dose to pelvis: 8200.
- Follow-up form, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment 2: Chemo concurrent type other: 5-Fluorouracil.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 791 days; disease-specific survival: no event (censored), 791 days; disease-free interval: no event (censored), 791 days; progression-free interval: no event (censored), 791 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EA-A43B-01A-81D-A242-01): tumor purity 0.38, ploidy 3.69, whole-genome doublings 1.
